Somatic mutation profile of tumor specimen TCGA-CV-A6JO-01B (aliquot TCGA-CV-A6JO-01B-11D-A34J-08) from TCGA case TCGA-CV-A6JO, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 69.5 years (25,377 days).
Specimen TCGA-CV-A6JO-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96117a2a-d516-4b21-b929-43f795746d3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A6JO-10A (Blood Derived Normal), aliquot TCGA-CV-A6JO-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1791ef8-e5c4-4445-af10-e95530733d0c

The open-access MAF lists 68 somatic variants for this specimen: 56 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 10, Frame Shift Del 3, RNA 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 24/124 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC134980.2 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as rs746293102, COSV100171807; called by mutect2, varscan2
- ACAP2 | c.1736C>T p.T579M | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.213); catalogued as rs139056381; called by muse, mutect2, varscan2
- ADAM20 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV99833506, COSV99833612; called by muse, mutect2, varscan2
- ATG4D | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs769398498, COSV100470267; called by muse, mutect2, varscan2
- BLM | c.1531C>A p.L511I | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1382968714, COSV100757265; called by mutect2, varscan2
- CASP8 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99965302, COSV99965639; called by muse, mutect2, varscan2
- CHD5 | c.3359C>T p.S1120L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99314307; called by muse, mutect2, varscan2
- DARS1 | c.1247A>G p.Y416C | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99927723; called by muse, mutect2
- DCBLD2 | c.1393C>A p.P465T | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV100472741; called by muse, mutect2, varscan2
- DNAH5 | c.12934G>C p.E4312Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.714); catalogued as COSV99451863; called by muse, mutect2, varscan2
- DSCAM | c.4004G>A p.R1335Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs571178062, COSV68025688; called by muse, mutect2, varscan2
- DSP | c.8536C>T p.R2846W | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV60939203; called by muse, mutect2, varscan2
- EPHB3 | c.1929A>C p.E643D | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100383182; called by muse, mutect2, varscan2
- FHDC1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as rs149221149; called by muse, mutect2
- FLG | c.8560T>G p.S2854A | Missense Mutation (SNP) | VAF 61/1143 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.278); catalogued as COSV100911843, COSV100912163; called by muse, mutect2
- FUS | c.1310A>G p.N437S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV99568851; called by muse, mutect2, varscan2
- FUT9 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs201254420, COSV56147106; called by muse, mutect2
- GCHFR | c.143A>C p.Y48S | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.129); catalogued as COSV99549150; called by muse, mutect2, varscan2
- HDGF | c.541del p.E181Rfs*144 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as COSV61975837; called by mutect2, pindel
- HHIP | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99667546; called by muse, mutect2, varscan2
- JPH2 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs750791531, COSV65902250; called by muse, mutect2, varscan2
- KMT2A | c.6184C>T p.R2062C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100630036, COSV63293801; called by muse, mutect2, varscan2
- KRTAP26-1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.053); catalogued as rs146155445, COSV62128788; called by muse, mutect2
- LYST | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as rs141312203; called by muse, mutect2, varscan2
- MOS | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465724519, COSV100322936; called by muse, mutect2
- MTMR4 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); catalogued as COSV60203230; called by muse, mutect2, varscan2
- NEK4 | c.1763A>C p.N588T | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV99237927; called by muse, mutect2, varscan2
- NOL4 | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1337938276, COSV52336798; called by muse, mutect2
- PPWD1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as rs951955153, COSV99731468; called by muse, mutect2, varscan2
- PRR23B | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61494170; called by muse, mutect2, varscan2
- PSD2 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as rs377562857; called by muse, mutect2
- RAD50 | c.837G>T p.K279N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs1561638972, COSV99529257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHOBTB1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs751927663, COSV61958256; called by muse, mutect2, varscan2
- SHROOM4 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56788246, COSV99173928; called by muse, mutect2, varscan2
- SLC34A3 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100746693; called by muse, mutect2
- SLIT3 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs767775691, COSV100268808; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 9/104 reads (9%) | PolyPhen benign (0.441); catalogued as rs368807164; called by muse, mutect2
- SUPT3H | c.406A>G p.S136G (on ENST00000371460 / NM_181356.3; = p.S125G on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100177674; called by muse, mutect2, varscan2
- TACC2 | c.8392+1G>A p.X2798_splice (on ENST00000334433; = p.X876_splice on NM_006997.4) | Splice Site (SNP) | VAF 13/139 reads (9%) | catalogued as COSV99587377; called by muse, mutect2
- TAS1R1 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs745386138, COSV60230169; called by muse, mutect2, varscan2
- TENT2 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1289443969, COSV99706260; called by muse, mutect2
- TRIP12 | c.977A>G p.Q326R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.838); catalogued as COSV99390675; called by muse, mutect2, varscan2
- UBR1 | c.1151A>G p.Y384C | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); catalogued as COSV99317567; called by muse, mutect2, varscan2
- UGT3A1 | c.863C>G p.A288G | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as COSV99955062; called by muse, mutect2
- USP32 | c.1877C>A p.P626H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV100342432; called by muse, mutect2, varscan2
- USP35 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777673245, COSV71572656; called by muse, mutect2
- YTHDC2 | c.4246C>A p.Q1416K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99363613; called by muse, mutect2, varscan2
- ZNF33A | c.1141G>T p.E381* (on ENST00000458705 / NM_006974.3; = p.E382* on NM_006954.2) | Nonsense Mutation (SNP) | VAF 22/124 reads (18%) | catalogued as COSV100276045; called by muse, mutect2, varscan2
- ZNF483 | c.1345G>A p.G449S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100493047; called by muse, mutect2, varscan2
- ZNF681 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.511); catalogued as COSV68076225; called by muse, mutect2, varscan2
- EEF1A1 | c.362_364del p.G121del | In Frame Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- HLA-DRA | c.70_79del p.W24Kfs*5 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | called by mutect2, pindel, varscan2
- IGHM | c.1088del p.V363Gfs*16 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- JMJD1C | c.4437dup p.I1480Yfs*16 | Frame Shift Ins (INS) | VAF 11/93 reads (12%) | called by mutect2, pindel, varscan2
- ACP5 | c.531C>T p.D177= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs369197756; called by muse, mutect2, varscan2
- COL19A1 | c.738A>G p.S246= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100506925, COSV59577409; called by muse, mutect2, varscan2
- FAT1 | c.12534G>C p.G4178= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as COSV101499465; called by muse, mutect2, varscan2
- KCNG1 | c.129G>A p.A43= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1245527335, COSV65368166; called by muse, mutect2, varscan2
- MAPKBP1 | c.3174C>A p.G1058= (on ENST00000456763 / NM_001128608.2; = p.G1052= on NM_014994.3) | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99529565, COSV99529870; called by muse, mutect2
- MED24 | c.750C>T p.L250= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs751559929, COSV62422097; called by muse, mutect2, varscan2
- NAV3 | c.630G>A p.S210= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs751011496, COSV57120195; called by muse, mutect2, varscan2
- NFATC1 | c.2601G>A p.A867= (on ENST00000427363 / NM_001278669.2; = p.A854= on NM_172387.3) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs368703221; called by mutect2, varscan2
- NUP210L | c.2868T>A p.P956= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV55158360; called by muse, mutect2, varscan2
- TUBA3C | c.309C>T p.Y103= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as rs114178008, COSV67139668; called by muse, mutect2, varscan2
- PIGL | c.336-17816C>T | Intron (SNP) | VAF 5/33 reads (15%) | catalogued as rs369999556, COSV99848740; called by muse, mutect2, varscan2
- TXNRD3 | n.685T>A | RNA (SNP) | VAF 6/98 reads (6%) | catalogued as COSV101275044; called by muse, mutect2
